Surgical pathology report (de-identified scan), TCGA case TCGA-X8-AAAR, project TCGA-ESCA (Esophageal Carcinoma), tissue source site St. Joseph's Hospital Arizona, specimen TCGA-X8-AAAR-01A (Primary Tumor).

Tumor ID: **Redacted**
Normal ID: **Redacted**

ICD O-3
Adenocarcinoma NOS 8140/3
Site: Esophagus, distal
third C15.5
JNJ 5/16/14

Diagnosis:

Distal esophagus carcinoma, summary:

Specimen; Esophagus and proximal stomach

Procedure: Esophagogastrectomy

Tumor site: Distal esophagus

Relationship of tumor to esophagogastric junction: Tumor midpoint lies in the distal esophagus and tumor involves the esophagogastric junction

Tumor size: 3.0cm

Histologic type: Adenocarcinoma

Histologic grade: Well differentiated, G1.

Microscopic Description:

Microscopic performed on all histologic sections.

Source: NCI Genomic Data Commons file cef26ec6-e6a7-49b5-b9da-a0de4f1d14bd (TCGA-X8-AAAR.EF3FB18D-977A-4BE4-80B4-39DE30650B7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).